Gene-level copy-number profile of tumor specimen TCGA-CV-6941-01A from TCGA case TCGA-CV-6941, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 51.5 years (18,812 days).
Specimen TCGA-CV-6941-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.ca39edab-2932-4e62-9d5c-4588dff4c2ee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6941-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a941f81-3f49-42cf-8917-17368d6f196e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 93; copy number 2: 18,305; copy number 3: 25,755; copy number 4: 11,502; copy number 5: 3,339; copy number 6: 477; copy number 7: 150; copy number 8: 98; copy number 9: 20; copy number 11: 45; copy number 13: 16; copy number 23: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6941-01A-11D-1910-01): tumor purity 0.56, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 335 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:182,140,036–183,072,486, 12 genes, copy number 9: PDE1A, AC012500.1, RN7SL267P, DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10.
- chr3:99,817,837–100,181,732, 1 gene, copy number 8 (within-gene range 5–8): CMSS1.
- chr3:100,132,903–100,695,479, 11 genes, copy number 8 (within-gene range 5–8): AC129803.1, TMEM30CP, DUSP12P1, VTI1BP1, TBC1D23, NIT2, TOMM70, LNP1, TMEM45A, ADGRG7, AC069223.1.
- chr3:113,019,468–113,184,377, 1 gene, copy number 8 (within-gene range 5–8): AC078785.1.
- chr3:113,142,350–113,167,819, 1 gene, copy number 8: LINC02044.
- chr3:152,118,173–152,496,813, 6 genes, copy number 8: AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1.
- chr3:166,721,458–168,095,924, 20 genes, copy number 8: AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1.
- chr3:169,003,022–169,038,416, 1 gene, copy number 8: LINC01997.
- chr3:170,222,424–170,454,733, 6 genes, copy number 8: PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11.
- chr3:170,423,103–170,423,162, 1 gene, copy number 8: MIR6828.
- chr3:170,459,548–170,586,075, 2 genes, copy number 8 (within-gene range 5–8): SLC7A14, KRT8P13.
- chr3:172,301,654–173,336,965, 18 genes, copy number 8 (within-gene range 5–8): AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1.
- chr3:187,997,422–188,890,671, 7 genes, copy number 8 (within-gene range 5–8): AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1.
- chr7:53,366,058–55,344,958, 30 genes, copy number 9–23: RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr12:66,767–5,406,651, 135 genes, copy number 7 (broad region; genes not listed).
- chr12:19,404,045–20,370,262, 14 genes, copy number 7: AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1.
- chr12:20,449,655–20,450,083, 1 gene, copy number 7: UBE2L2.
- chr22:28,883,572–30,472,017, 68 genes, copy number 8–11 (within-gene range 3–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 80. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
